Surgical pathology report (de-identified scan), TCGA case TCGA-43-6771, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-6771-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Left upper lobe
- B. Level 5 lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer.

GROSS DESCRIPTION

A. Submitted fresh for tissue procurement labeled "left upper lobe" is a lobe of lung tissue which has been amputated at the level of its principle bronchus and blood vessels. The bronchial profiles that are present consists of three bronchi, each approximately 8 to 9 mm across. They are grossly unremarkable. Some vascular stumps are present at the point of amputation as well. There is some anthracotic tissue present which may represent some hilar lymph nodes. The visceral pleural surface of the lobe is intact although there is a small area of adhesion and thickening overlying an obviously large intraparenchymal tumor mass. The remainder of the parenchyma is anthracotic without focal lesion. The lung was serially sectioned and this reveals a very large tumor mass present in the center of the lobe which has a extensively necrotic center. The tumor mass measures maximally 6 cm. across. There is a rim of granular brown black tumor tissue present which appears to extend to the visceral pleural surface. The center of the tumor is necrotic with a creamy yellowish red appearance. Fresh tissue from [REDACTED] normal lung is submitted for procurement as per request of [REDACTED]. Sections through the remainder of the lung show no other [REDACTED] lesions. Sections after fixation.

BLOCK SUMMARY: 1 - Bronchial and vascular margins; 2 - possible lymph nodes; 3-8 - tumor including pleu [REDACTED] - random non-tumorous lung section. RS-9 after fixation. [REDACTED]

B. Received fresh, labeled "Level 5 lymph node", are multiple black-pink, irregular soft tissue fragments, which have an aggregate measurement of 0.7 x 0.4 x 0.3 [REDACTED]. The specimens are entirely submitted in one cassette. AS-1 [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

Microscopic sections of the left upper lobe tumor reveals a squamous cell carcinoma which has variable histology. Portions of the tumor are moderately differentiated and show evidence of keratinization and well-defined intracellular bridges. Other parts of the tumor have a sarcomatoid appearance and focally develop a biphasic appearance with moderately differentiated squamous carcinoma and spindle cell elements intermingling in a carcinosarcomatous-like pattern. The finding of the histology is present in the following template.

[page 2 of 2]
Histologic type: Squamous cell carcinoma.
Histologic grade: Poorly differentiated.
Primary tumor (pT): 6 cm mass which does not involve the visceral pleural surface (pT2).
Margins of resection: Negative.
Direct extension of tumor: Absent.
Venous (large vessel) invasion: Negative.
Arterial (large vessel) invasion: Negative.
Lymphatic (small vessel) invasion: Negative.
Regional lymph nodes (pN): Two peribronchial lymph nodes and the level 5 lymph node (part B) are negative for metastatic carcinoma. (pN0)
Distant metastasis (pM): Could not be assessed. (pMX)

5,3

DIAGNOSIS

- A. Lung, left upper lobectomy:
Invasive, poorly differentiated squamous cell carcinoma with focal sarcomatoid features.
The tumor does not involve the visceral pleural surface.
Bronchial and vascular margins of resection are free of tumor.
Two bronchial lymph nodes negative for metastatic carcinoma (0/2).
- B. Lymph node, level 5, resection:
Fibrofatty tissue and sclerotic lymph node tissue negative for metastatic carcinoma.
-

--- End Of Report ---

Source: NCI Genomic Data Commons file 910aacd6-1b87-4a9b-b7ca-390447148060 (TCGA-43-6771.09FBD8E1-9F86-47C1-ABEA-FD8E96366908.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).